Somatic mutation profile of tumor specimen TCGA-EE-A29B-06A (aliquot TCGA-EE-A29B-06A-11D-A197-08) from TCGA case TCGA-EE-A29B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.3 years (26,769 days).
Specimen TCGA-EE-A29B-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf616767-082e-4a1e-a055-97c9dc5c434e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29B-10A (Blood Derived Normal), aliquot TCGA-EE-A29B-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97ab4e71-9ff4-487f-84e0-2b0e51e674bc

The open-access MAF lists 665 somatic variants for this specimen: 447 protein-altering or splice-affecting, 201 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 412, Silent 201, Nonsense Mutation 24, Intron 8, Splice Region 5, RNA 4, Splice Site 3, 3'UTR 2, 3'Flank 2, Frame Shift Del 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs730880403, COSV51757334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2
- ABCA13 | c.12826G>A p.D4276N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs765749513, COSV68943080; called by muse, mutect2, varscan2
- ABCA13 | c.13316A>T p.Y4439F | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68943084; called by muse, mutect2, varscan2
- ABCC8 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 115/219 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56845907; called by muse, mutect2, varscan2
- ABCE1 | c.1264-1G>A p.X422_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV56846103; called by muse, mutect2, varscan2
- ABCG5 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53182089; called by muse, mutect2, varscan2
- AC100868.1 | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51837546; called by muse, mutect2, varscan2
- ACAD11 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53893272; called by muse, mutect2, varscan2
- ACTN2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs767763639, COSV63971679; called by muse, mutect2, varscan2
- ADAM20 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV56454015; called by muse, mutect2, varscan2
- ADAM7 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51534747; called by muse, mutect2, varscan2
- ADAMTS17 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs776618280, COSV51472757; called by muse, mutect2
- ADAMTS19 | c.1564C>T p.L522F | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV50731739, COSV50798522; called by muse, mutect2, varscan2
- ADARB1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1179624314, COSV62341784; called by muse, mutect2, varscan2
- ADGRL2 | c.2573C>T p.S858F (on ENST00000370717 / NM_001366005.1; = p.S845F on NM_012302.4) | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV54650682; called by muse, mutect2, varscan2
- ADGRL4 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as COSV66058992; called by muse, mutect2, varscan2
- ADH1A | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1268425754, COSV52924241; called by muse, mutect2, varscan2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 139/270 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, mutect2, varscan2
- AFDN | c.3532A>G p.N1178D | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV60036764; called by muse, mutect2, varscan2
- AFP | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV56923824; called by muse, mutect2, varscan2
- AGTR1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762020328, CM1514785, COSV62557225, COSV62558442; called by muse, mutect2, varscan2
- ALPG | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs1283282258, COSV54964788; called by muse, mutect2, varscan2
- ANAPC1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs769251816, COSV61974112; called by mutect2, varscan2
- ANK3 | c.3124T>G p.L1042V (on ENST00000280772 / NM_001320874.2; = p.L176V on NM_001149.3) | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs970527330, COSV55043245; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7124G>A p.R2375Q | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV51839947; called by muse, mutect2, varscan2
- ANKRD26 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs779236210, COSV65792709; called by muse, mutect2, varscan2
- AP5B1 | c.1757C>A p.A586E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57502173; called by muse, mutect2, varscan2
- ARHGAP10 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60594423; called by muse, mutect2, varscan2
- ARMC4 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs151193419, COSV59465626; called by muse, mutect2
- ASXL3 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52456541, COSV52457687; called by muse, mutect2, varscan2
- ATP13A5 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1484164068, COSV60875294; called by muse, varscan2
- ATP1A3 | c.323G>A p.W108* (on ENST00000545399 / NM_001256214.2; = p.W95* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 46/104 reads (44%) | catalogued as COSV57484916; called by muse, mutect2, varscan2
- ATP2B2 | c.3305T>G p.V1102G (on ENST00000352432; = p.V1068G on NM_001683.5) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV59488506; called by muse, mutect2, varscan2
- B4GALNT4 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV57321394; called by muse, mutect2, varscan2
- BCL2L12 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775763410, COSV55862220; called by muse, mutect2, varscan2
- BDH1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV64017676; called by muse, varscan2
- BDKRB2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs992787256, COSV60013501; called by muse, mutect2, varscan2
- BEST3 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58298658; called by muse, mutect2, varscan2
- BHMT | c.913T>C p.Y305H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.794); catalogued as COSV57153495; called by muse, mutect2, varscan2
- BLK | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs1234737422, COSV52049247; called by muse, mutect2, varscan2
- BMT2 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 38/109 reads (35%) | catalogued as COSV51774584; called by muse, mutect2, varscan2
- BRCA2 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs765924757, COSV66447820, COSV66457643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTC | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs782271380, COSV67547196; called by muse, mutect2, varscan2
- C12orf54 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV58359888; called by muse, mutect2, varscan2
- C9orf64 | c.926A>G p.N309S | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV59032077; called by muse, mutect2, varscan2
- CACNG7 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as COSV55812894; called by muse, mutect2
- CARF | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57546161; called by muse, mutect2, varscan2
- CATSPERB | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56421924; called by muse, mutect2, varscan2
- CBR3 | c.676T>G p.C226G | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51740670; called by muse, mutect2, varscan2
- CD163 | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV63129186; called by muse, mutect2, varscan2
- CDH18 | c.2303G>A p.G768E | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV56900013; called by muse, mutect2, varscan2
- CDH18 | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56900038; called by muse, mutect2, varscan2
- CDH6 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV54063684; called by muse, mutect2, varscan2
- CDH8 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 20/22 reads (91%) | catalogued as rs267604590, COSV100182320, COSV54846997; called by muse, mutect2, varscan2
- CEACAM5 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.435); catalogued as rs781992472, COSV55750460; called by muse, mutect2, varscan2
- CES1 | c.1303C>T p.R435W (on ENST00000361503 / NM_001025194.2; = p.R434W on NM_001266.5) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs376976316, COSV62085308; called by muse, mutect2, varscan2
- CETN1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV59120783; called by muse, mutect2, varscan2
- CFAP45 | c.50A>T p.N17I | Missense Mutation (SNP) | VAF 162/227 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV63647919; called by muse, mutect2, varscan2
- CFHR3 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs1460615140, COSV66401464; called by muse, mutect2, varscan2
- CHD1 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.568); catalogued as COSV52336555, COSV52342038; called by muse, mutect2, varscan2
- CHRNB3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV51493022; called by muse, mutect2, varscan2
- CILP2 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs1312774460, COSV52272416; called by muse, mutect2, varscan2
- CLDN2 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61020564; called by muse, mutect2, varscan2
- CLEC5A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396699; called by muse, mutect2, varscan2
- CLSTN2 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71717979; called by muse, mutect2, varscan2
- CMTM5 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV59304697; called by muse, mutect2, varscan2
- CNGB3 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV60684268; called by muse, mutect2, varscan2
- CNOT4 | c.1919C>T p.A640V (on ENST00000541284 / NM_001190850.1; = p.A566V on NM_013316.4) | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV64156071; called by muse, mutect2, varscan2
- CNTN5 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201638465, COSV54278829; called by muse, mutect2, varscan2
- CNTNAP2 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as rs267601388, COSV62143231, COSV62177141; called by muse, mutect2, varscan2
- COG7 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs1031815684, COSV56149047; called by muse, mutect2, varscan2
- COL1A1 | c.3025C>T p.P1009S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs794727663, COSV56802323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV65664763, COSV65671619; called by muse, mutect2, varscan2
- COL5A3 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs763085937, COSV53405906; called by muse, mutect2, varscan2
- COL6A6 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62017163; called by muse, mutect2, varscan2
- COLEC10 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60520508, COSV60522335; called by muse, mutect2, varscan2
- COPA | c.843-1G>A p.X281_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as COSV54097576; called by muse, mutect2, varscan2
- CPLANE2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV65056553; called by muse, mutect2
- CPZ | c.1844A>G p.E615G (on ENST00000360986 / NM_001014447.3; = p.E604G on NM_003652.3) | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59921418; called by muse, mutect2, varscan2
- CREB3L2 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1202623725, COSV57791995; called by muse, mutect2, varscan2
- CSF1R | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as rs371692872, COSV53828022; called by muse, mutect2, varscan2
- CSMD2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs781404797, COSV53876686, COSV53911244; called by muse, mutect2, varscan2
- CYLC1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61409762; called by muse, mutect2, varscan2
- CYP19A1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV53056958; called by muse, mutect2, varscan2
- CYP3A4 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV60500916; called by muse, mutect2, varscan2
- DBX2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV60335902; called by muse, mutect2, varscan2
- DCAF6 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 86/125 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as rs770698749, COSV56574665; called by muse, mutect2, varscan2
- DCDC1 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs868553033, COSV60833573; called by muse, mutect2, varscan2
- DGKK | c.3169C>T p.P1057S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV65706258; called by muse, mutect2, varscan2
- DMBT1 | c.3131G>A p.G1044E (on ENST00000338354 / NM_001377530.1; = p.G545E on NM_004406.3) | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1394768225, COSV57533630; called by muse, mutect2, varscan2
- DMRTC2 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54185633, COSV99523465; called by muse, mutect2, varscan2
- DNAH5 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776400781, COSV54219811, COSV54228968; called by muse, mutect2, varscan2
- DSC1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57141474, COSV99937583; called by muse, mutect2, varscan2
- DSC3 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1253348459, COSV64571562; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV50050926; called by muse, mutect2, varscan2
- DYNC1I1 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV61455337; called by muse, mutect2, varscan2
- EIF4EBP1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs767454211, COSV58774023; called by muse, mutect2, varscan2
- EMC7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV56626427; called by muse, mutect2, varscan2
- ENOX2 | c.559C>T p.R187C (on ENST00000338144 / NM_001382520.1; = p.R158C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57647076, COSV57650021; called by muse, mutect2, varscan2
- ENPEP | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV54446739; called by muse, mutect2, varscan2
- EPHA1 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.073); catalogued as COSV51968414; called by muse, mutect2, varscan2
- EPHB6 | c.2818C>T p.L940F | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773308911; called by muse, mutect2, varscan2
- EYA2 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs991612630, COSV57937794; called by muse, mutect2, varscan2
- F7 | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1455009854, COSV60644895; called by muse, mutect2, varscan2
- FAM124A | c.580C>T p.L194F (on ENST00000322475 / NM_001242312.2; = p.L230F on NM_145019.4) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54474292; called by muse, mutect2, varscan2
- FAM83B | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV60919122; called by muse, mutect2, varscan2
- FAM83G | c.2310G>A p.M770I | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58755113; called by muse, mutect2, varscan2
- FAR2 | c.246T>G p.I82M | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV51723127; called by muse, mutect2, varscan2
- FBLIM1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as COSV60028448; called by muse, mutect2, varscan2
- FBLN2 | c.3198G>A p.T1066= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as COSV55480602, COSV55482878; called by muse, mutect2, varscan2
- FBLN5 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV50902045; called by muse, varscan2
- FBLN7 | c.1273A>G p.N425D | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV55615361; called by muse, mutect2, varscan2
- FBN3 | c.6806T>A p.V2269D | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54452740; called by muse, mutect2, varscan2
- FGB | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs775891227, COSV57417397; called by muse, mutect2, varscan2
- FLG2 | c.3499G>A p.G1167S | Missense Mutation (SNP) | VAF 92/137 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); catalogued as rs1276655238, COSV66166502; called by muse, mutect2, varscan2
- FNDC7 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs769004072, COSV54750530; called by muse, mutect2, varscan2
- FOXO4 | c.1211C>T p.S404F | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV58574682; called by muse, mutect2, varscan2
- FSIP2 | c.19577G>A p.G6526E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58077766; called by muse, mutect2, varscan2
- FUT9 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV56142126; called by muse, mutect2, varscan2
- GABRA6 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50877454; called by muse, mutect2, varscan2
- GALNT14 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61102259; called by muse, mutect2, varscan2
- GIMAP8 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV56229625; called by muse, mutect2, varscan2
- GK2 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs377582691; called by muse, mutect2, varscan2
- GLYATL2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs745546178, COSV54848887; called by muse, mutect2, varscan2
- GPR139 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100429949, COSV58501556; called by muse, mutect2, varscan2
- GPR155 | c.1028T>A p.I343K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs780719552, COSV55037204; called by muse, mutect2, varscan2
- GRID2 | c.1942T>C p.Y648H | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56171163; called by muse, mutect2, varscan2
- GRM1 | c.3205C>T p.P1069S | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1234992505, COSV51108346; called by muse, mutect2, varscan2
- GRM8 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV58799958; called by muse, mutect2, varscan2
- GUCY2C | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV53786543; called by muse, mutect2, varscan2
- HCN1 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100299771, COSV57492798, COSV57541621; called by muse, mutect2, varscan2
- HELLS | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as rs1348121888, COSV53294231; called by muse, mutect2, varscan2
- HEPH | c.2812G>A p.E938K (on ENST00000343002; = p.E671K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV57958731; called by muse, mutect2, varscan2
- HEPHL1 | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.438); catalogued as COSV59889344; called by muse, mutect2, varscan2
- HERC4 | c.2929C>T p.H977Y (on ENST00000395198 / NM_022079.3; = p.H969Y on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as COSV53268240; called by muse, mutect2, varscan2
- HLA-DPB1 | c.557T>G p.V186G | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69602260; called by muse, mutect2
- HOXA3 | c.1130A>G p.N377S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.112); catalogued as rs370472758; called by muse, mutect2, varscan2
- HROB | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs760544676, COSV55368436; called by muse, mutect2, varscan2
- IGHV3-20 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); catalogued as rs782694588; called by muse, mutect2, varscan2
- IGSF1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 37/39 reads (95%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as CM164150, COSV63835928; called by muse, mutect2, varscan2
- IGSF10 | c.5087A>G p.Q1696R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV56781401; called by muse, mutect2, varscan2
- IL23R | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as COSV61372604; called by muse, mutect2, varscan2
- IMPDH1 | c.562C>T p.P188S (on ENST00000470772 / NM_001142573.2; = p.P274S on NM_000883.4) | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.063); catalogued as COSV58314895; called by muse, mutect2, varscan2
- INHA | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.147); catalogued as COSV54712414; called by muse, mutect2, varscan2
- IRS1 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59333303; called by muse, mutect2, varscan2
- ISM1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV52602350; called by muse, mutect2, varscan2
- ITGA2B | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs974615642, COSV52231033; called by muse, mutect2, varscan2
- ITGB5 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV56146443; called by muse, mutect2
- ITGB5 | c.1103T>A p.I368N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56146453; called by muse, mutect2
- KCNH1 | c.1612G>A p.D538N (on ENST00000271751 / NM_172362.3; = p.D511N on NM_002238.4) | Missense Mutation (SNP) | VAF 92/124 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55068562; called by muse, mutect2, varscan2
- KCNH5 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs567491628, COSV59751574; called by muse, mutect2, varscan2
- KCNH8 | c.3169C>T p.Q1057* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV60456075; called by muse, mutect2, varscan2
- KCNQ5 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59647751; called by muse, mutect2, varscan2
- KDR | c.3188G>A p.G1063E | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763517390, COSV55757585; called by muse, mutect2, varscan2
- KIAA0319 | c.2969G>A p.R990K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.97); catalogued as COSV65496096; called by muse, mutect2, varscan2
- KIF14 | c.4465G>A p.E1489K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV66259749; called by muse, mutect2, varscan2
- KIF22 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV50713895; called by muse, varscan2
- KLHL13 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV53244388; called by muse, mutect2, varscan2
- KMT2C | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV51282844, COSV51422023; called by muse, mutect2, varscan2
- KRAS | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV55511879; called by muse, mutect2
- KRT10 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV54088142, COSV54088254; called by muse, varscan2
- KRT23 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as rs897151182, COSV52926966, COSV52927053; called by muse, mutect2, varscan2
- KRT5 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV52858726; called by muse, mutect2, varscan2
- KRT8 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs386834222; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT85 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs373376889; called by muse, mutect2, varscan2
- LAD1 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV66211988; called by muse, mutect2, varscan2
- LAMA5 | c.1160A>T p.Y387F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as rs1409913368, COSV53352581; called by muse, mutect2, varscan2
- LAMB3 | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.362); catalogued as COSV61915122; called by muse, mutect2, varscan2
- LGI1 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV65057351; called by muse, mutect2, varscan2
- LIFR | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV54684145; called by muse, mutect2, varscan2
- LINGO2 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58056775; called by muse, mutect2, varscan2
- LMO3 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53780911; called by muse, mutect2, varscan2
- LOX | c.968T>G p.F323C | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50236856; called by muse, mutect2, varscan2
- LOXL2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767167523, COSV66690336; called by muse, mutect2, varscan2
- LPIN1 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV56762263; called by muse, mutect2, varscan2
- LPO | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.7); PolyPhen benign (0.067); catalogued as rs867133288, COSV51856618, COSV51860333; called by muse, mutect2, varscan2
- LRP1B | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs538520838, COSV67184425; called by muse, mutect2, varscan2
- LRP6 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 172/413 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs139800650; called by muse, mutect2, varscan2
- LRRC10 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV64060002; called by muse, mutect2, varscan2
- LRRC7 | c.3271C>T p.Q1091* (on ENST00000651989 / NM_001370785.2; = p.Q1058* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV50409451; called by muse, mutect2, varscan2
- LRRTM3 | c.1462A>C p.T488P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV63660927; called by muse, mutect2, varscan2
- LUZP1 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs199684288, COSV100034477, COSV56498287; called by muse, mutect2, varscan2
- LYST | c.3374A>G p.E1125G | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.619); catalogued as COSV67702973; called by muse, mutect2, varscan2
- MAEL | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.949); catalogued as COSV63303791, COSV63305496; called by muse, mutect2, varscan2
- MAP1B | c.2879A>G p.E960G | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV57093514; called by muse, mutect2, varscan2
- MAP3K13 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53983072; called by muse, mutect2, varscan2
- MAP3K13 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV53983096; called by muse, mutect2, varscan2
- MAPK8 | c.796T>A p.Y266N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV64408297; called by muse, mutect2, varscan2
- MDC1 | c.5128A>T p.I1710F | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV64522995; called by muse, mutect2, varscan2
- MECOM | c.922C>T p.P308S (on ENST00000468789 / NM_001105078.4; = p.P496S on NM_004991.4) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV52959050; called by muse, mutect2, varscan2
- MEIOC | c.2267T>C p.I756T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1027862272, COSV63439344; called by muse, mutect2, varscan2
- METTL6 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as rs1188842776, COSV67541773; called by muse, mutect2, varscan2
- MFSD4A | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65655959; called by muse, varscan2
- MGAM | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs957482156, COSV71884944; called by muse, mutect2, varscan2
- MGAM | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs749121609, COSV72073544; called by muse, mutect2, varscan2
- MGAT4A | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53845207; called by muse, mutect2, varscan2
- MICAL2 | c.5003C>T p.S1668F | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as COSV56284080; called by muse, mutect2, varscan2
- MMD2 | c.767G>A p.R256K (on ENST00000404774 / NM_001100600.2; = p.R232K on NM_198403.4) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs370661719; called by muse, mutect2, varscan2
- MS4A14 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs758194109, COSV55732905; called by muse, mutect2, varscan2
- MS4A5 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as COSV55739707; called by muse, mutect2, varscan2
- MSH3 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54144334; called by muse, mutect2, varscan2
- MUC16 | c.4136C>T p.P1379L | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs766458028, COSV67443071; called by muse, mutect2, varscan2
- MUC17 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV60279435; called by muse, mutect2, varscan2
- MUC17 | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60279439; called by muse, mutect2, varscan2
- MYH2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV55431122; called by muse, mutect2, varscan2
- MYH4 | c.5398C>T p.R1800C | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770067160, COSV55111784; called by muse, mutect2, varscan2
- MYH4 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55111795; called by muse, mutect2, varscan2
- MYH6 | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59304708; called by muse, mutect2, varscan2
- MYH6 | c.4829G>A p.R1610H | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs758792342, COSV62447721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK2 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV65658458; called by muse, mutect2, varscan2
- MYO1E | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV55682290; called by muse, mutect2, varscan2
- MYOM2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as rs756665371, COSV50701875; called by muse, mutect2, varscan2
- MYOM3 | c.3695C>T p.T1232I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs750765424, COSV58389348; called by muse, mutect2, varscan2
- NCAPH2 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs747525172, COSV52686462; called by muse, mutect2, varscan2
- NEBL | c.2335C>T p.H779Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV65801299; called by muse, mutect2, varscan2
- NEBL | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as rs765610685, COSV65799475; called by muse, mutect2, varscan2
- NEK8 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV52042780; called by muse, mutect2, varscan2
- NEUROD4 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs764870162, COSV54470339; called by mutect2, varscan2
- NEUROD4 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54470348; called by muse, mutect2, varscan2
- NINL | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV53998283; called by muse, mutect2, varscan2
- NLRP2 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as rs1490209747, COSV54752140; called by muse, mutect2, varscan2
- NLRP8 | c.2664G>A p.W888* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV52583086; called by muse, mutect2, varscan2
- NOMO1 | c.2687C>T p.S896F | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773903170, COSV55056893; called by muse, mutect2, varscan2
- NOS1 | c.3880G>A p.D1294N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57606331; called by muse, mutect2, varscan2
- NOTCH2 | c.6655C>T p.P2219S | Missense Mutation (SNP) | VAF 190/503 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as rs1386606005, COSV56680938; called by muse, mutect2, varscan2
- NPAP1 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.607); catalogued as COSV61504125; called by muse, mutect2, varscan2
- NPAP1 | c.3358C>T p.Q1120* | Nonsense Mutation (SNP) | VAF 43/91 reads (47%) | catalogued as COSV61504132; called by muse, mutect2, varscan2
- NPBWR2 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs1417442678, COSV63899753; called by muse, mutect2, varscan2
- NPBWR2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63899758; called by muse, mutect2, varscan2
- NPHS2 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as COSV62634508; called by muse, mutect2, varscan2
- NPY1R | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56713237; called by muse, mutect2, varscan2
- NR1H4 | c.665T>C p.L222P (on ENST00000551379 / NM_001206993.2; = p.L208P on NM_005123.4) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1042693689, COSV51849170; called by muse, mutect2, varscan2
- NR5A2 | c.1377A>C p.L459F (on ENST00000367362 / NM_205860.3; = p.L413F on NM_003822.5) | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV52644804; called by muse, mutect2, varscan2
- NTNG1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53962109; called by muse, mutect2, varscan2
- NUGGC | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV58432174; called by muse, mutect2, varscan2
- NUP205 | c.601A>G p.K201E | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs1175072940, COSV53654619; called by muse, mutect2, varscan2
- NWD1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as COSV60337354; called by muse, mutect2, varscan2
- OBSCN | c.14131G>A p.V4711M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1383836487, COSV52737847; called by muse, mutect2, varscan2
- OBSCN | c.17807G>A p.R5936Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759267582, COSV52737876; called by muse, mutect2, varscan2
- OR10Q1 | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as COSV57469622; called by muse, mutect2, varscan2
- OR13C9 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV52240542, COSV52242086; called by muse, mutect2, varscan2
- OR1B1 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.733); catalogued as COSV59171114, COSV59172487; called by muse, mutect2, varscan2
- OR2A12 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV68821018; called by muse, mutect2, varscan2
- OR2K2 | c.151G>A p.G51R (on ENST00000374428; = p.G22R on NM_205859.2) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1464227632; called by muse, mutect2, varscan2
- OR4C13 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.873); catalogued as rs868965139, COSV73648608; called by muse, mutect2, varscan2
- OR52B4 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV68768566, COSV68769571; called by muse, mutect2, varscan2
- OR5B17 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868743937, COSV62159822; called by muse, mutect2, varscan2
- OR5H15 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62947322, COSV62947829; called by muse, mutect2, varscan2
- OR6C75 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV58551180; called by muse, mutect2, varscan2
- OR6K2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62743049; called by muse, mutect2, varscan2
- OR6N1 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 89/125 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as COSV58647345, COSV58650137; called by muse, mutect2, varscan2
- OR8B4 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV62069148; called by muse, mutect2, varscan2
- OR8D1 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100766485, COSV63441685; called by muse, mutect2, varscan2
- OR8G1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV58379659; called by muse, mutect2, varscan2
- OSBPL5 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55139267; called by muse, mutect2, varscan2
- OTOF | c.4553C>T p.A1518V (on ENST00000272371 / NM_194248.3; = p.A751V on NM_004802.4) | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55495068; called by muse, mutect2, varscan2
- OTOP3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs369170606, COSV60912176; called by muse, mutect2, varscan2
- PADI3 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV64933892; called by muse, mutect2, varscan2
- PAK2 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV59079044; called by muse, mutect2, varscan2
- PAK3 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV53270108; called by muse, mutect2, varscan2
- PAPPA | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.725); catalogued as COSV60277063; called by muse, mutect2, varscan2
- PCDH18 | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV61266248; called by muse, mutect2, varscan2
- PCDHA1 | c.2237G>A p.G746E | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.589); catalogued as rs377323471, COSV65372523; called by muse, mutect2, varscan2
- PCDHA12 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as rs782082764, COSV56475916; called by muse, mutect2, varscan2
- PCDHA7 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65341650; called by muse, mutect2, varscan2
- PCDHA8 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65334671; called by muse, mutect2, varscan2
- PCDHB1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60629372; called by muse, mutect2, varscan2
- PCDHB12 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV53392857, COSV53401120; called by muse, mutect2, varscan2
- PCDHB16 | c.884A>T p.N295I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV53357400; called by muse, mutect2, varscan2
- PCDHB8 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.16); catalogued as COSV50753714; called by muse, mutect2
- PCDHB9 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.099); catalogued as COSV53375009; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCDHGA2 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV53895165; called by muse, mutect2, varscan2
- PCDHGA3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53895175, COSV53932691, COSV99542394; called by muse, mutect2, varscan2
- PCDHGB5 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53895188; called by muse, mutect2, varscan2
- PCMTD2 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV55058987; called by muse, mutect2, varscan2
- PDE1A | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59513780; called by muse, mutect2, varscan2
- PDE1A | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV59513828; called by muse, mutect2, varscan2
- PDE1C | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV58502785; called by muse, mutect2, varscan2
- PDE1C | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV58502796; called by muse, mutect2, varscan2
- PDE8B | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1414540761, COSV53731612; called by muse, mutect2, varscan2
- PEX6 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs977542433, COSV55101632, COSV55103925; called by muse, mutect2, varscan2
- PGA3 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs559550682, COSV57711363; called by muse, mutect2, varscan2
- PHF2 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63678300, COSV63682040; called by muse, mutect2, varscan2
- PHLPP1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.253); catalogued as COSV53021486; called by muse, mutect2, varscan2
- PKHD1L1 | c.8377G>A p.E2793K | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs267601719, COSV65736548; called by muse, mutect2, varscan2
- PLA2R1 | c.3353C>T p.T1118I | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1433621342, COSV51774625; called by muse, mutect2, varscan2
- PLCE1 | c.4381C>T p.P1461S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV53335894; called by muse, mutect2, varscan2
- PLEK | c.913A>T p.N305Y | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52250422; called by muse, mutect2, varscan2
- PLEKHH2 | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV56749465, COSV56760489; called by muse, mutect2, varscan2
- PMS1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866127846, COSV59714519; called by muse, mutect2, varscan2
- PNLIPRP3 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1463879090, COSV65046896; called by muse, mutect2, varscan2
- PPFIA1 | c.1435C>T p.L479F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV54131307; called by muse, mutect2, varscan2
- PPM1J | c.961T>A p.F321I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53516638; called by muse, mutect2, varscan2
- PPP1R13L | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs750806921, COSV100714888, COSV62907828; called by muse, mutect2, varscan2
- PPP1R9A | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56880598, COSV56912818; called by muse, mutect2, varscan2
- PRKCB | c.1068C>T p.V356= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as COSV57764936; called by muse, mutect2, varscan2
- PRKG1 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV64766173; called by muse, mutect2, varscan2
- PRSS12 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.745); catalogued as rs773003498, COSV56603908; called by muse, mutect2
- PRSS55 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV60807623; called by muse, mutect2
- PRSS55 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV60807629; called by muse, mutect2, varscan2
- PSMD5 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV52959841; called by muse, mutect2, varscan2
- PTCH1 | c.4328G>T p.G1443V | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.36); catalogued as rs864622100, COSV59461945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTX4 | c.1312G>A p.E438K (on ENST00000447419 / NM_001328608.2; = p.E433K on NM_001013658.1) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1472079248, COSV53514080; called by muse, mutect2, varscan2
- QDPR | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV55549204; called by muse, mutect2, varscan2
- QRICH2 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV53150576; called by muse, mutect2, varscan2
- RAB23 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs145669565, COSV58097253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB4A | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV64207086; called by muse, mutect2, varscan2
- RABEPK | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52334004; called by muse, mutect2, varscan2
- RAF1 | c.483T>A p.N161K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV52574402; called by muse, mutect2, varscan2
- RAG2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV57556283; called by muse, mutect2, varscan2
- RB1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 28/38 reads (74%) | catalogued as CM030498, COSV57294911; called by muse, mutect2, varscan2
- RELN | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV58984901; called by muse, mutect2, varscan2
- RHAG | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57702961; called by muse, mutect2, varscan2
- RHBDL2 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56706782; called by muse, mutect2, varscan2
- RNF19A | c.903T>A p.C301* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV61992242; called by muse, mutect2, varscan2
- RNF220 | c.807C>T p.S269= | Splice Region (SNP) | VAF 22/54 reads (41%) | catalogued as rs1237059306, COSV62404543; called by muse, varscan2
- RORB | c.1237G>A p.D413N (on ENST00000396204 / NM_001365023.1; = p.D402N on NM_006914.4) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.097); catalogued as rs776761648, COSV65332563; called by muse, mutect2, varscan2
- RPH3AL | c.217A>T p.I73F | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV58738104; called by muse, mutect2, varscan2
- RPP38 | c.451A>G p.S151G | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as COSV65381312; called by muse, mutect2, varscan2
- RPS3A | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56838935; called by muse, mutect2, varscan2
- RWDD1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.332); catalogued as COSV63972139; called by muse, mutect2, varscan2
- RYR1 | c.10637A>T p.D3546V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62088158; called by muse, mutect2, varscan2
- SALL1 | c.3289C>T p.P1097S | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs775124413, COSV51752937; called by muse, mutect2, varscan2
- SAMD9 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV66072871; called by muse, mutect2, varscan2
- SARDH | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs766104484, COSV53831799; called by muse, mutect2, varscan2
- SATB1 | c.1577G>C p.G526A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58667269, COSV58669352; called by muse, mutect2, varscan2
- SCG3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.298); catalogued as COSV55019930; called by muse, mutect2, varscan2
- SDS | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV57452552; called by muse, mutect2, varscan2
- SEC23A | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as COSV56970321; called by muse, mutect2, varscan2
- SELPLG | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as COSV57311322; called by muse, mutect2, varscan2
- SEPTIN12 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs866928089, COSV51615420; called by muse, mutect2, varscan2
- SERPINA10 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs2232697, COSV100003661; called by muse, mutect2, varscan2
- SERPINB11 | c.499A>T p.K167* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV66956392; called by muse, mutect2, varscan2
- SERPINI2 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV52984150; called by muse, mutect2, varscan2
- SGMS1 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100693422, COSV62369102; called by muse, mutect2, varscan2
- SGSM1 | c.3096C>T p.I1032= (on ENST00000400359 / NM_001039948.4; = p.I971= on NM_133454.3) | Splice Region (SNP) | VAF 14/27 reads (52%) | catalogued as COSV68508630; called by muse, mutect2, varscan2
- SH2D7 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60925857; called by muse, mutect2
- SH2D7 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV60925871; called by muse, mutect2
- SLC10A2 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs201392859; called by muse, mutect2, varscan2
- SLC13A2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV58992437; called by muse, mutect2, varscan2
- SLC17A3 | c.1117C>T p.L373F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV57759389; called by muse, mutect2, varscan2
- SLC22A2 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65265608; called by muse, mutect2, varscan2
- SLC26A9 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 354/499 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61600734; called by muse, mutect2, varscan2
- SLC38A11 | c.826C>T p.L276F (on ENST00000409149 / NM_001351539.1; = p.L254F on NM_173512.2) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.633); catalogued as COSV58052011; called by muse, mutect2, varscan2
- SLC5A9 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1348367913, COSV52581885; called by muse, mutect2
- SLC6A11 | c.1137T>A p.F379L | Missense Mutation (SNP) | VAF 117/256 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54389546, COSV54391326; called by muse, mutect2, varscan2
- SLC8A1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as COSV60470255; called by muse, varscan2
- SLC8A1 | c.774T>G p.F258L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.53); catalogued as COSV60470274; called by muse, varscan2
- SLC8A3 | c.1785G>A p.V595= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as COSV53687512; called by muse, mutect2, varscan2
- SLC9B2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1279351107, COSV60017357; called by muse, mutect2, varscan2
- SLCO6A1 | c.1132-1G>A p.X378_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as rs764992878, COSV65805360, COSV65806351; called by muse, mutect2
- SMYD3 | c.545C>T p.S182F (on ENST00000490107 / NM_001375962.1; = p.S123F on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV63625490; called by muse, mutect2, varscan2
- SNX33 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV57912659; called by muse, mutect2, varscan2
- SPOCK1 | c.706A>G p.R236G | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.819); catalogued as COSV56436097; called by muse, mutect2, varscan2
- SPOCK3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62715669, COSV62737011; called by muse, mutect2, varscan2
- SPR | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs369387459, COSV52298213; called by muse, mutect2, varscan2
- SRRM1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as rs1457157607; called by muse, mutect2, varscan2
- ST8SIA3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | PolyPhen benign (0.055); catalogued as COSV60653234; called by muse, mutect2, varscan2
- STOX1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1412858858, COSV53812763; called by muse, mutect2, varscan2
- STYXL2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV54801809; called by muse, mutect2
- SV2C | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59213456; called by muse, mutect2, varscan2
- SVEP1 | c.3338G>A p.G1113E | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57028499; called by muse, mutect2, varscan2
- SYT1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54032324; called by muse, mutect2, varscan2
- TAOK2 | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as COSV54232832; called by muse, mutect2, varscan2
- TAS1R2 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV64743502; called by muse, varscan2
- TBC1D16 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200514216, COSV59988670, COSV59988953; called by muse, mutect2, varscan2
- TBC1D24 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53545025; called by muse, mutect2, varscan2
- TC2N | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as rs766880081, COSV61746165, COSV61747755; called by muse, varscan2
- TF | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758425512, CM150774, COSV53917398; called by muse, mutect2, varscan2
- TGIF2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV65836218; called by muse, mutect2, varscan2
- TLX3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs928000019, COSV51538816; called by muse, mutect2, varscan2
- TMEM132D | c.3122A>T p.K1041I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV67158655; called by muse, mutect2, varscan2
- TMEM182 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV101305393, COSV68424179; called by muse, mutect2, varscan2
- TNC | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs866147837, COSV60780069; called by muse, mutect2, varscan2
- TNC | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs1167849583, COSV60780081; called by muse, mutect2
- TNFRSF10B | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV52390969; called by muse, mutect2, varscan2
- TNR | c.2855C>T p.A952V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54868901; called by muse, mutect2, varscan2
- TOP3A | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV58174739; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99160471; called by muse, varscan2
- TRHDE | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV53831780; called by muse, varscan2
- TRHDE | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV53831788; called by muse, varscan2
- TRIM29 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV59278913; called by muse, mutect2, varscan2
- TRIM59 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59086326; called by muse, mutect2, varscan2
- TRIM63 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV65327717; called by muse, varscan2
- TRPC4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.381); catalogued as COSV58989738; called by muse, mutect2, varscan2
- TRPC7 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV61452419; called by muse, mutect2, varscan2
- TTC38 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs914160315, COSV66843534; called by muse, mutect2, varscan2
- TTN | c.60538G>A p.A20180T (on ENST00000591111; = p.A12756T on NM_003319.4) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | PolyPhen benign (0.12); catalogued as COSV59874593; called by muse, mutect2, varscan2
- TTN | c.47554G>A p.E15852K (on ENST00000591111; = p.E8428K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | PolyPhen possibly damaging (0.879); catalogued as rs1046078803, COSV59874633; called by muse, mutect2, varscan2
- TTN | c.8531C>T p.S2844L (on ENST00000591111; = p.S2798L on NM_003319.4) | Missense Mutation (SNP) | VAF 50/114 reads (44%) | PolyPhen possibly damaging (0.591); catalogued as COSV59874699; called by muse, varscan2
- TTN | c.5266G>A p.E1756K (on ENST00000591111; = p.E1710K on NM_003319.4) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | PolyPhen probably damaging (0.994); catalogued as COSV59874793; called by muse, mutect2, varscan2
- TTN | c.2287G>A p.A763T (on ENST00000591111; = p.A717T on NM_003319.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | PolyPhen benign (0.009); catalogued as COSV59874847; called by muse, mutect2, varscan2
- UGT1A4 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100529955; called by muse, mutect2, varscan2
- UGT2B10 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV55318460; called by muse, mutect2, varscan2
- UGT2B11 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 33/63 reads (52%) | catalogued as COSV71422936; called by muse, mutect2, varscan2
- ULK1 | c.1655G>A p.C552Y | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58854418; called by muse, mutect2, varscan2
- URB2 | c.3045G>A p.M1015I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs759247481, COSV50981077; called by muse, mutect2, varscan2
- UROC1 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751617501, COSV52029909, COSV99331304; called by muse, mutect2, varscan2
- USH1C | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs138123405, COSV50044964; called by muse, mutect2, varscan2
- USP37 | c.2663C>T p.S888L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs4292082, COSV50285353; called by muse, mutect2, varscan2
- USP48 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as COSV57606931; called by muse, mutect2, varscan2
- USP6 | c.2801A>C p.Q934P | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.954); catalogued as COSV51473438; called by muse, mutect2, varscan2
- VARS1 | c.99G>A p.W33* | Nonsense Mutation (SNP) | VAF 142/325 reads (44%) | catalogued as COSV65151544; called by muse, mutect2, varscan2
- VENTX | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58083980; called by muse, mutect2, varscan2
- VPS13B | c.10103G>A p.G3368E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100661864; called by muse, mutect2, varscan2
- VPS13C | c.7538A>G p.Y2513C (on ENST00000644861 / NM_020821.3; = p.Y2470C on NM_017684.5) | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1418309876, COSV51120532; called by muse, mutect2, varscan2
- VWF | c.2093G>A p.R698K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs745612376, COSV54610967; called by muse, mutect2, varscan2
- WDR24 | c.1712G>A p.G571D (on ENST00000248142; = p.G441D on NM_032259.4) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as COSV50196335; called by muse, mutect2, varscan2
- WDR3 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV62522372; called by muse, varscan2
- WDR7 | c.4036C>T p.L1346F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1298140873, COSV54347463; called by muse, mutect2, varscan2
- WDR72 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1391144265, COSV64741358; called by muse, mutect2, varscan2
- WIPF3 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV54206101; called by muse, mutect2, varscan2
- WIPI2 | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs751688954, COSV56586941; called by muse, varscan2
- ZBTB4 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1409316482, COSV60976513; called by muse, mutect2, varscan2
- ZC3H7A | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63268154; called by muse, mutect2, varscan2
- ZC3HAV1L | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs769768641, COSV51964063; called by muse, mutect2, varscan2
- ZFP41 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV58086001; called by muse, mutect2, varscan2
- ZMYM5 | c.1894A>G p.S632G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.187); catalogued as COSV61987116; called by muse, mutect2, varscan2
- ZNF33B | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.996); catalogued as COSV63941793; called by muse, mutect2, varscan2
- ZNF438 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV59191949; called by muse, mutect2, varscan2
- ZNF532 | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as rs752760317, COSV60171712; called by muse, mutect2, varscan2
- ZNF534 | c.394G>A p.E132K (on ENST00000332323 / NM_001143939.3; = p.E119K on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV56513944; called by muse, mutect2, varscan2
- ZNF585B | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV57214472; called by muse, mutect2, varscan2
- ZNF592 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1409239282, COSV55434936; called by muse, mutect2, varscan2
- ZNF644 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs1193317157, COSV61345835; called by muse, mutect2, varscan2
- ZSCAN1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV56601394; called by muse, mutect2, varscan2
- ADAMTSL4 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C3orf33 | c.827C>T p.S276F (on ENST00000340171 / NM_001308229.2; = p.S233F on NM_173657.2) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- CCDC178 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ENO2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- FAT3 | c.4489G>A p.V1497I | Missense Mutation (SNP) | VAF 157/332 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.4490T>G p.V1497G | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- IGHM | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.8); called by muse, mutect2, varscan2
- MUC20 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- OR2K2 | c.152G>T p.G51V (on ENST00000374428; = p.G22V on NM_205859.2) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8G5 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PRAMEF18 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC9A4 | c.773_774del p.I258Rfs*44 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- SNAPC2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- VPS13B | c.10102G>A p.G3368R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF101 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ZNF507 | c.1721dup p.L574Ffs*7 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- ZNF680 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF836 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ABCB11 | c.1278C>G p.T426= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV55584870; called by muse, mutect2, varscan2
- ABI2 | c.216C>T p.V72= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV53689671; called by muse, mutect2, varscan2
- ABL1 | c.1467C>T p.I489= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as COSV59324441; called by muse, mutect2, varscan2
- ADAM15 | c.828C>T p.N276= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs1195222243, COSV55125092; called by muse, mutect2, varscan2
- ADAM28 | c.1956C>T p.I652= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs777423480, COSV56097541; called by muse, varscan2
- ADAMDEC1 | c.1152C>T p.F384= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV56473968; called by muse, mutect2, varscan2
- ADAMTS18 | c.2265C>T p.Y755= | Silent (SNP) | VAF 33/34 reads (97%) | catalogued as COSV51398410; called by muse, mutect2, varscan2
- ADAMTSL4 | c.75G>A p.Q25= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as COSV99647702; called by muse, mutect2, varscan2
- ADCY1 | c.1885C>T p.L629= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV52029662, COSV52030105; called by muse, mutect2, varscan2
- ADCY10 | c.336G>A p.L112= | Silent (SNP) | VAF 39/209 reads (19%) | catalogued as COSV63238425; called by muse, mutect2, varscan2
- AGBL2 | c.561C>T p.V187= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV54089871; called by muse, mutect2, varscan2
- AHNAK2 | c.11370C>T p.S3790= | Silent (SNP) | VAF 87/213 reads (41%) | catalogued as COSV60907167; called by muse, mutect2
- ALDH16A1 | c.1593C>T p.F531= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs747326977, COSV53192434; called by muse, mutect2, varscan2
- ANKH | c.807T>C p.S269= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV52476483; called by muse, mutect2, varscan2
- ANO4 | c.2349C>T p.I783= (on ENST00000392977 / NM_001286615.2; = p.I748= on NM_178826.4) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV54584537; called by muse, mutect2, varscan2
- AP1G2 | c.1080C>T p.A360= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV55337283; called by muse, mutect2, varscan2
- ARAP3 | c.2955T>G p.R985= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV53348430; called by muse, mutect2, varscan2
- ARHGAP30 | c.2514G>A p.R838= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV63514720; called by muse, mutect2, varscan2
- ARHGEF1 | c.735C>T p.F245= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV61526135; called by muse, mutect2, varscan2
- ARHGEF17 | c.4869C>T p.L1623= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs747165387, COSV55229174; called by muse, varscan2
- ARMC4 | c.2619G>A p.G873= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2
- ARSB | c.813C>T p.S271= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs757019634, COSV53718719; called by muse, mutect2, varscan2
- ATP10A | c.2226C>T p.F742= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs770529746, COSV63513146; called by muse, mutect2, varscan2
- ATP10B | c.2664G>A p.G888= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs770488838, COSV59143355; called by muse, mutect2
- ATP13A5 | c.2604A>T p.S868= | Silent (SNP) | VAF 44/102 reads (43%) | called by muse, varscan2
- BANK1 | c.1842C>T p.P614= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV59837957; called by muse, mutect2, varscan2
- BPIFB2 | c.738G>A p.R246= | Silent (SNP) | VAF 73/149 reads (49%) | catalogued as rs748276111, COSV50063086; called by muse, mutect2, varscan2
- BRWD3 | c.1803C>T p.F601= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as rs749932873, COSV64743664; called by muse, mutect2, varscan2
- BTBD16 | c.564C>T p.I188= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV53260505; called by muse, mutect2, varscan2
- BTNL8 | c.783C>T p.F261= | Silent (SNP) | VAF 106/227 reads (47%) | catalogued as COSV51456722; called by muse, mutect2, varscan2
- C8orf58 | c.864C>T p.S288= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs942296848, COSV51514394; called by muse, mutect2, varscan2
- CACNA1E | c.909C>T p.F303= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1166897617, COSV62381525; called by muse, mutect2, varscan2
- CACNG6 | c.402G>A p.K134= | Silent (SNP) | VAF 22/35 reads (63%) | catalogued as COSV53165592; called by muse, mutect2, varscan2
- CARMIL3 | c.3021C>T p.T1007= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV57724556; called by muse, mutect2, varscan2
- CCDC42 | c.825G>A p.K275= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV53447997; called by muse, mutect2, varscan2
- CCNT1 | c.1809C>T p.S603= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs1464250236, COSV56063065, COSV99980772; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5316C>T p.H1772= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs748693383, COSV62571891; called by muse, mutect2, varscan2
- CEP192 | c.6459C>T p.F2153= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV58059621; called by muse, mutect2, varscan2
- CFAP65 | c.2731C>T p.L911= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58557640; called by muse, mutect2, varscan2
- CHKA | c.1347C>T p.F449= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV55834427; called by muse, mutect2
- CHRD | c.927G>A p.E309= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs745903696, COSV52605221; called by muse, mutect2, varscan2
- CNGA3 | c.1158G>A p.L386= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs146142409; called by muse, mutect2, varscan2
- CNGB1 | c.3006C>T p.I1002= | Silent (SNP) | VAF 79/89 reads (89%) | catalogued as COSV51897299; called by muse, mutect2, varscan2
- CNTN3 | c.1926T>C p.G642= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV55162621; called by muse, mutect2, varscan2
- CNTNAP2 | c.1356G>A p.G452= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs1283772865, COSV62143226; called by muse, mutect2, varscan2
- COL4A2 | c.4917A>C p.S1639= | Silent (SNP) | VAF 37/58 reads (64%) | catalogued as COSV64624616; called by muse, mutect2, varscan2
- CPNE5 | c.1737C>T p.S579= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV55194367; called by muse, mutect2, varscan2
- CPT1C | c.192C>T p.F64= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV54917390; called by muse, mutect2, varscan2
- CSMD2 | c.9138G>A p.L3046= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV53876640; called by muse, mutect2, varscan2
- CSMD2 | c.5478C>T p.I1826= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs761883622, COSV53876669; called by muse, mutect2, varscan2
- CYP21A2 | c.699G>A p.K233= | Silent (SNP) | VAF 69/438 reads (16%) | catalogued as COSV64472868; called by muse, mutect2, varscan2
- CYP2C9 | c.1461C>T p.F487= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as COSV53246276; called by muse, mutect2, varscan2
- DCAF6 | c.1479G>A p.L493= (on ENST00000312263 / NM_001349778.1; = p.L513= on NM_018442.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 48/74 reads (65%) | catalogued as COSV56574681; called by muse, mutect2, varscan2
- DEFB112 | c.231C>T p.I77= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as COSV59182324; called by muse, mutect2, varscan2
- DES | c.1335G>A p.T445= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs780984657, COSV64661343; called by muse, varscan2
- DNAH5 | c.1890C>T p.A630= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- DNAH7 | c.11292C>T p.F3764= | Silent (SNP) | VAF 71/141 reads (50%) | catalogued as rs775574754, COSV56751050; called by muse, mutect2, varscan2
- DNM2 | c.2433C>T p.S811= (on ENST00000355667 / NM_001005360.3; = p.S807= on NM_004945.3) | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV53033090; called by muse, varscan2
- DPYD | c.504C>T p.I168= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV64590229; called by muse, mutect2, varscan2
- DRD3 | c.294C>T p.F98= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV55678432; called by muse, mutect2, varscan2
- DYNC2LI1 | c.792C>T p.F264= | Silent (SNP) | VAF 137/314 reads (44%) | catalogued as rs749713577, COSV53182086; called by muse, mutect2, varscan2
- ENO2 | c.324C>T p.A108= | Silent (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- EPHB6 | c.2817C>T p.A939= | Silent (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- EPS8L3 | c.51C>T p.S17= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV62608701; called by muse, mutect2, varscan2
- ESRRG | c.345G>A p.K115= | Silent (SNP) | VAF 133/184 reads (72%) | catalogued as COSV63149026; called by muse, mutect2, varscan2
- EXPH5 | c.382C>T p.L128= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV56198663; called by muse, varscan2
- F2RL1 | c.798C>T p.I266= | Silent (SNP) | VAF 174/410 reads (42%) | catalogued as COSV56994985; called by muse, mutect2, varscan2
- FABP1 | c.198G>A p.G66= | Silent (SNP) | VAF 75/176 reads (43%) | catalogued as COSV55557725; called by muse, mutect2, varscan2
- FCRL1 | c.759G>A p.S253= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs535623313, COSV63823697; called by muse, mutect2, varscan2
- FGF3 | c.261C>T p.A87= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV61925167; called by muse, mutect2, varscan2
- FLNC | c.4299C>T p.F1433= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs766671322, COSV57949861; called by muse, mutect2, varscan2
- FOXD4L4 | c.657C>T p.F219= | Silent (SNP) | VAF 16/94 reads (17%) | called by mutect2, varscan2
- FREM2 | c.2226G>C p.V742= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54827616; called by muse, mutect2, varscan2
- FRMD3 | c.327G>A p.V109= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV58454068; called by muse, mutect2, varscan2
- GAL3ST1 | c.1089G>A p.Q363= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV58891858; called by muse, mutect2, varscan2
- GALNT8 | c.765G>A p.R255= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV52894439; called by muse, mutect2, varscan2
- GUCY2C | c.3204G>A p.K1068= | Silent (SNP) | VAF 59/109 reads (54%) | catalogued as COSV53786527; called by muse, mutect2, varscan2
- HABP2 | c.1293G>A p.V431= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV63488368; called by muse, mutect2, varscan2
- HEPH | c.3252C>T p.P1084= (on ENST00000343002; = p.P817= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as COSV57958746; called by muse, mutect2
- HMGCLL1 | c.810C>T p.I270= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as rs147515881, COSV51440300; called by muse, mutect2, varscan2
- HPSE2 | c.1047G>A p.L349= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as COSV65180038; called by muse, mutect2, varscan2
- HSPA12B | c.153C>T p.V51= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs776050974, COSV54765538; called by muse, mutect2, varscan2
- ISX | c.318C>T p.Y106= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs755648880, COSV58085503; called by muse, mutect2, varscan2
- ITGA10 | c.1155G>A p.G385= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV65195932; called by muse, mutect2, varscan2
- ITPRID2 | c.1098T>C p.S366= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV57469376; called by muse, mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2
- KIAA1217 | c.216C>T p.P72= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV64600168; called by muse, mutect2, varscan2
- KIF26B | c.1266G>A p.G422= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV63636362; called by muse, mutect2, varscan2
- KRT79 | c.144C>T p.A48= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57938206; called by muse, mutect2, varscan2
- KRT8 | c.1413G>A p.G471= | Silent (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.660C>T p.V220= (on ENST00000418998 / NM_001377303.1; = p.V130= on NM_015478.7) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV64230482; called by muse, mutect2, varscan2
- LAMB3 | c.1866C>T p.S622= | Silent (SNP) | VAF 75/127 reads (59%) | catalogued as COSV61915129; called by muse, mutect2, varscan2
- LAPTM4B | c.570C>T p.A190= (on ENST00000445593; = p.A99= on NM_018407.6) | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV71453707, COSV71453709; called by muse, mutect2, varscan2
- LDB3 | c.1911G>A p.A637= | Silent (SNP) | VAF 49/90 reads (54%) | catalogued as rs150710377; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAMDC4 | c.1204C>T p.L402= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV56031767; called by muse, mutect2, varscan2
- MATK | c.327G>A p.E109= (on ENST00000310132 / NM_139355.3; = p.E110= on NM_002378.4) | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1353147720, COSV59552992; called by muse, mutect2, varscan2
- ME1 | c.924G>A p.G308= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV63837477; called by muse, mutect2
- METTL2A | c.771C>T p.I257= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV61043521; called by muse, mutect2, varscan2
- MGAT4C | c.486C>T p.H162= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV59829660, COSV59831463; called by muse, mutect2, varscan2
- MIGA1 | c.963C>T p.I321= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs753678013, COSV66222630; called by muse, mutect2, varscan2
- MINK1 | c.3222C>T p.T1074= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs777000028, COSV53416658; called by muse, mutect2, varscan2
- MLIP | c.333C>T p.F111= | Silent (SNP) | VAF 60/119 reads (50%) | catalogued as rs201706379; called by muse, mutect2, varscan2
- MLST8 | c.369G>A p.R123= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV57026308; called by muse, mutect2, varscan2
- MUC16 | c.42060C>T p.T14020= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV66689647; called by muse, mutect2, varscan2
- MYBPC2 | c.1824G>A p.A608= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs373184181, COSV63093208; called by muse, mutect2, varscan2
- MYH8 | c.1476C>T p.F492= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as rs1567687933, COSV67959417; called by muse, mutect2, varscan2
- MYLK | c.2844C>T p.P948= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs772331257, COSV60604305; called by muse, mutect2, varscan2
- MYO3B | c.588C>T p.F196= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as COSV58693613; called by muse, mutect2, varscan2
- NEUROD4 | c.663C>T p.L221= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV54470355; called by muse, mutect2
- NINL | c.2067C>T p.V689= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs1210547274, COSV53998291; called by muse, mutect2, varscan2
- NLRP10 | c.906C>T p.P302= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as COSV60778573; called by muse, mutect2, varscan2
- NLRP3 | c.111C>T p.I37= | Silent (SNP) | VAF 38/50 reads (76%) | catalogued as rs145314485; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOTCH1 | c.6327C>T p.I2109= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs756964890, COSV53026858; called by muse, mutect2, varscan2
- NOVA1 | c.1389C>T p.F463= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs769569205, COSV57471940; called by muse, mutect2, varscan2
- NPHS1 | c.2490C>T p.L830= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs114635782, COSV62286253; called by muse, varscan2
- NPIPB15 | c.771T>C p.T257= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV70436533; called by muse, mutect2, varscan2
- NPTX2 | c.843G>A p.L281= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV55716118; called by muse, mutect2, varscan2
- NRXN1 | c.2487G>A p.Q829= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV58435793; called by muse, mutect2, varscan2
- OPRL1 | c.846C>T p.F282= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs370852885; called by muse, mutect2, varscan2
- OR13C4 | c.504C>T p.F168= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs1295369265, COSV52925706; called by muse, mutect2, varscan2
- OR1L4 | c.564C>T p.L188= | Silent (SNP) | VAF 62/211 reads (29%) | catalogued as COSV52339573, COSV99413957; called by muse, mutect2, varscan2
- OR2B11 | c.657T>C p.L219= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as rs374651468; called by muse, mutect2, varscan2
- OR2T29 | c.66C>T p.F22= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV100148231; called by mutect2, varscan2
- OR2T33 | c.177C>T p.F59= | Silent (SNP) | VAF 119/204 reads (58%) | catalogued as COSV58813839; called by muse, mutect2, varscan2
- OR2T5 | c.66C>T p.F22= | Silent (SNP) | VAF 39/174 reads (22%) | catalogued as COSV63540386; called by mutect2, varscan2
- OR4K1 | c.633C>T p.F211= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV53458691, COSV99578762; called by muse, mutect2, varscan2
- OR52H1 | c.903C>T p.I301= (on ENST00000322653; = p.I307= on NM_001005289.1) | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as COSV59504810; called by muse, mutect2, varscan2
- OR52K2 | c.828C>T p.I276= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs780621028, COSV57834535; called by muse, mutect2, varscan2
- OR5M1 | c.324G>A p.V108= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV73201954; called by muse, mutect2, varscan2
- OR5M11 | c.481C>T p.L161= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1291541183, COSV73141626; called by muse, mutect2, varscan2
- OR6B3 | c.600C>T p.F200= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV60112544; called by muse, mutect2, varscan2
- OR6C76 | c.381G>A p.L127= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV60388534; called by muse, mutect2, varscan2
- P2RY10 | c.792T>A p.I264= | Silent (SNP) | VAF 56/57 reads (98%) | catalogued as COSV50680321, COSV50687426; called by muse, mutect2, varscan2
- PALM | c.468G>A p.L156= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as COSV52766570; called by muse, mutect2, varscan2
- PGLYRP4 | c.510A>G p.E170= | Silent (SNP) | VAF 55/181 reads (30%) | catalogued as COSV62834516; called by muse, mutect2, varscan2
- PLCB3 | c.1248G>T p.V416= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV54185624; called by muse, mutect2, varscan2
- PLXDC2 | c.1497G>A p.A499= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs147255630; called by muse, mutect2, varscan2
- POM121L12 | c.336C>T p.L112= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs775113311, COSV68692176, COSV68692518; called by muse, mutect2, varscan2
- PRAMEF6 | c.1209C>T p.I403= | Silent (SNP) | VAF 35/93 reads (38%) | called by mutect2, varscan2
- RBBP8 | c.216C>T p.V72= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV59090442; called by muse, mutect2, varscan2
- RHBDD2 | c.222C>T p.I74= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV50086701; called by muse, mutect2, varscan2
- RNF43 | c.2232T>A p.P744= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV68456823; called by muse, mutect2, varscan2
- RNF6 | c.1398G>A p.R466= | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as COSV60417749; called by muse, mutect2, varscan2
- RP1 | c.507G>C p.A169= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as COSV55109605; called by muse, mutect2, varscan2
- RPE65 | c.888G>A p.R296= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs778422718, COSV52012975; called by muse, mutect2, varscan2
- RYR1 | c.11217G>A p.G3739= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs148659292; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN11A | c.1020G>A p.T340= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs267599814, COSV56565234; called by muse, mutect2, varscan2
- SCN4A | c.3849C>T p.S1283= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs772627391, COSV71125520; called by muse, mutect2
- SCN5A | c.4521G>A p.Q1507= (on ENST00000333535 / NM_198056.3; = p.Q1506= on NM_000335.5) | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV61115294; called by muse, mutect2, varscan2
- SCN5A | c.3699G>A p.K1233= (on ENST00000333535 / NM_198056.3; = p.K1232= on NM_000335.5) | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV61115307; called by muse, mutect2, varscan2
- SEPTIN9 | c.570C>T p.I190= (on ENST00000427177 / NM_001113491.2; = p.I172= on NM_006640.4) | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV61202075; called by muse, mutect2, varscan2
- SERTAD2 | c.351C>T p.P117= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs368818619; called by muse, mutect2, varscan2
- SH2D1B | c.90A>G p.L30= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV63391943; called by muse, mutect2, varscan2
- SLC10A5 | c.1308C>T p.F436= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV72828210; called by muse, mutect2, varscan2
- SLC16A3 | c.828C>T p.F276= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as rs758447400, COSV66428988; called by muse, mutect2, varscan2
- SLC18A3 | c.1236C>T p.R412= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV60319791, COSV60321731; called by muse, mutect2, varscan2
- SLC33A1 | c.952C>T p.L318= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV63946666; called by muse, mutect2, varscan2
- SLC35A2 | c.375G>A p.Q125= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as COSV54429127; called by muse, mutect2, varscan2
- SLC5A12 | c.1077G>A p.V359= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs372952413; called by muse, mutect2, varscan2
- SLC7A9 | c.354C>T p.I118= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs369365355; called by muse, mutect2, varscan2
- SMARCA4 | c.4410C>T p.I1470= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV60786091; called by muse, mutect2, varscan2
- SNAPC2 | c.480G>A p.Q160= | Silent (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- SNCAIP | c.234G>A p.R78= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV54401801; called by muse, mutect2, varscan2
- SNRNP200 | c.4350C>T p.L1450= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs867495235, COSV60487002; called by muse, mutect2, varscan2
- SPNS2 | c.924C>T p.A308= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV61229079; called by muse, mutect2, varscan2
- SRRM1 | c.846C>T p.S282= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100104837; called by muse, mutect2, varscan2
- SRRM2 | c.1875T>C p.S625= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV57067926; called by muse, mutect2, varscan2
- SYNDIG1 | c.393G>A p.G131= | Silent (SNP) | VAF 53/102 reads (52%) | catalogued as COSV65231825; called by muse, mutect2, varscan2
- SYT16 | c.1041C>T p.P347= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1376770308, COSV70854875; called by muse, mutect2, varscan2
- SYT8 | c.1002C>T p.S334= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs774908594, COSV53288549; called by muse, mutect2, varscan2
- TACC2 | c.3495C>T p.C1165= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV57745543; called by muse, mutect2, varscan2
- TBC1D8B | c.2385C>T p.S795= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as COSV52175453; called by muse, varscan2
- TENM1 | c.3144G>A p.T1048= | Silent (SNP) | VAF 44/47 reads (94%) | catalogued as rs763660900, COSV64424110; called by muse, mutect2, varscan2
- TENM4 | c.3729C>T p.L1243= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs373240552, COSV53606370; called by muse, mutect2, varscan2
- TMEM131L | c.1965C>T p.F655= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV53640656; called by muse, mutect2, varscan2
- TMEM132A | c.1890G>A p.T630= (on ENST00000453848 / NM_178031.3; = p.T631= on NM_017870.4) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs374171061; called by muse, mutect2, varscan2
- TMEM132E | c.2127G>A p.K709= (on ENST00000321639; = p.K799= on NM_001304438.2) | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs370979692; called by muse, mutect2, varscan2
- TNFSF14 | c.648C>T p.V216= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs143839697, COSV55589725; called by muse, mutect2, varscan2
- TP63 | c.349C>T p.L117= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV53195844; called by muse, mutect2, varscan2
- TPSD1 | c.150C>T p.P50= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV52973946; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1011G>A p.R337= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99160462; called by muse, mutect2, varscan2
- TRPM2 | c.4419C>T p.I1473= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV55965594; called by muse, mutect2, varscan2
- TTN | c.26922C>T p.F8974= (on ENST00000591111; = p.F8047= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV59874672; called by muse, mutect2, varscan2
- TTN | c.19347C>T p.F6449= (on ENST00000591111; = p.F5522= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs751734958, COSV59874684; called by muse, mutect2, varscan2
- TTN | c.7944C>T p.S2648= (on ENST00000591111; = p.S2602= on NM_003319.4) | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV59874749; called by muse, mutect2, varscan2
- USE1 | c.267C>T p.F89= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV55726677; called by muse, mutect2, varscan2
- USP19 | c.2874C>T p.S958= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as COSV60044799; called by muse, mutect2, varscan2
- USP32 | c.633G>A p.R211= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV56263772; called by muse, mutect2, varscan2
- UTP18 | c.1653C>T p.H551= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs1412294215, COSV56582156; called by muse, mutect2, varscan2
- VCPIP1 | c.3312C>T p.A1104= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as rs758336849, COSV60045953; called by muse, mutect2, varscan2
- VEPH1 | c.408C>T p.F136= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100747480, COSV62875643; called by muse, mutect2, varscan2
- VPS39 | c.507C>T p.S169= (on ENST00000348544 / NM_001301138.2; = p.S158= on NM_015289.5) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs776810745, COSV58787568; called by muse, mutect2, varscan2
- WDR7 | c.1524C>T p.F508= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs1286530387, COSV54347455; called by muse, mutect2, varscan2
- WNT16 | c.732G>A p.K244= (on ENST00000222462 / NM_057168.2; = p.K234= on NM_016087.2) | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs990346067, COSV55974754; called by muse, mutect2, varscan2
- YTHDF1 | c.1413G>A p.K471= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs745319206, COSV64832479; called by muse, mutect2, varscan2
- ZBTB34 | c.1179C>T p.L393= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59859316; called by muse, mutect2, varscan2
- ZNF101 | c.108C>T p.T36= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100543609; called by muse, mutect2, varscan2
- ZNF208 | c.2493G>A p.K831= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV68100090; called by muse, mutect2, varscan2
- ZNF213 | c.216C>G p.R72= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV67727449; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.606C>T p.T202= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs200561889, COSV58349294; called by muse, mutect2, varscan2
- ZNF836 | c.1014C>T p.T338= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100441214; called by muse, mutect2, varscan2
- AATK | c.756-317C>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100452704; called by muse, mutect2, varscan2
- AGAP7P | n.2028T>C | RNA (SNP) | VAF 5/38 reads (13%) | called by mutect2, varscan2
- AL109984.1 | n.186+1043G>A | Intron (SNP) | VAF 24/48 reads (50%) | catalogued as COSV63750174; called by muse, mutect2, varscan2
- AL163540.1 | n.151T>C | RNA (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888434 A>T | 3'Flank (SNP) | VAF 54/80 reads (68%) | catalogued as COSV58043645; called by muse, mutect2, varscan2
- GDF5 | c.-398+625G>A | Intron (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100698809; called by muse, mutect2, varscan2
- GEM | c.*1G>A | 3'UTR (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99891183; called by muse, mutect2, varscan2
- MGAM | c.4618+250G>A | Intron (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- NACA | c.71-3507C>T | Intron (SNP) | VAF 30/71 reads (42%) | called by muse, varscan2
- NLRP4 | c.-1G>A | 5'UTR (SNP) | VAF 34/84 reads (40%) | catalogued as COSV100015791; called by muse, mutect2, varscan2
- NXF5 | n.390G>A | RNA (SNP) | VAF 92/98 reads (94%) | catalogued as rs764670404, COSV53789559, COSV53789771; called by muse, mutect2, varscan2
- PCP4 | c.*2G>A | 3'UTR (SNP) | VAF 13/37 reads (35%) | catalogued as rs766373750, COSV100150588; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2009C>T | Intron (SNP) | VAF 11/34 reads (32%) | catalogued as COSV56907480; called by muse, mutect2, varscan2
- PSG6 | chr19:42902434 C>T | 3'Flank (SNP) | VAF 69/169 reads (41%) | catalogued as rs1251430984, COSV51829864; called by muse, mutect2, varscan2
- SLC7A2 | c.-22-4398C>T | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2
- SSPOP | n.14969C>T | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as rs762008943, COSV65126916; called by mutect2, varscan2
- USH1C | c.1284+1128C>T | Intron (SNP) | VAF 13/28 reads (46%) | catalogued as rs780885203, COSV50032972, COSV99139617; called by muse, mutect2, varscan2
